Somatic mutation profile of tumor specimen MMRF_2002_1_BM_CD138pos (aliquot MMRF_2002_1_BM_CD138pos_T1_KBS5U_L07213) from MMRF case MMRF_2002, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.1 years (25,986 days).
Specimen MMRF_2002_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dd44011-743c-42b8-9f5d-74252faf7f96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2002_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2002_1_PB_Whole_C2_KBS5U_L07214; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed7099b5-bba7-472d-8d1c-2651aeaa83d2

The open-access MAF lists 150 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 41, Intron 22, Silent 16, 5'UTR 9, RNA 4, 5'Flank 4, Nonsense Mutation 3, Splice Region 3, 3'Flank 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008397.2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1042552963; called by muse, mutect2, varscan2
- CCDC178 | c.2176G>T p.E726* (on ENST00000383096 / NM_001105528.3; = p.E688* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100285538; called by muse, mutect2
- CLOCK | c.22A>G p.S8G | Missense Mutation (SNP) | VAF 120/344 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs764433881; called by muse, varscan2
- COL4A2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs568655744, COSV100847183; called by muse, mutect2, varscan2
- DPP10 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59714364; called by muse, mutect2, varscan2
- FLT4 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as rs747401546; called by muse, mutect2, varscan2
- FREM2 | c.2518C>T p.Q840* | Nonsense Mutation (SNP) | VAF 11/150 reads (7%) | catalogued as rs866708727, COSV99747307; called by muse, mutect2
- FXR2 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1434629124; called by muse, mutect2, varscan2
- H4C2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs754767006; called by muse, mutect2, varscan2
- IGKJ3 | c.27A>T p.K9N | Missense Mutation (SNP) | VAF 73/159 reads (46%) | catalogued as rs149374792; called by muse, varscan2
- IRS1 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1393539515, COSV59336433; called by muse, mutect2, varscan2
- KLK9 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as rs1414342421, COSV99143881; called by muse, mutect2, varscan2
- KRT86 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.65); catalogued as rs774291422; called by muse, mutect2, varscan2
- LRCH1 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.047); catalogued as rs1266478263; called by muse, mutect2, varscan2
- PCSK5 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV70453585; called by muse, mutect2, varscan2
- PDZRN4 | c.2981A>T p.K994M (on ENST00000402685 / NM_001164595.2; = p.K736M on NM_013377.4) | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416165346, COSV54220083; called by muse, mutect2, varscan2
- PPP1R36 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1054130144; called by muse, mutect2, varscan2
- PPP1R9B | c.2444A>G p.N815S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs376937049; called by muse, mutect2, varscan2
- PRDM15 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs765889816; called by muse, mutect2, varscan2
- PRSS36 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs768201640, COSV51637922; called by muse, mutect2, varscan2
- RALGAPB | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV53441602; called by muse, mutect2, varscan2
- TIMELESS | c.326A>G p.H109R | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1312986601; called by muse, mutect2, varscan2
- ZNF337 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs746271113; called by muse, mutect2
- ZNF672 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60638306; called by muse, mutect2, varscan2
- ASXL3 | c.5599C>A p.Q1867K | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2
- C6orf58 | c.914-1G>C p.X305_splice | Splice Site (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- CCDC178 | c.2177A>C p.E726A (on ENST00000383096 / NM_001105528.3; = p.E688A on NM_198995.3) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CDH17 | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN6 | c.2416T>C p.Y806H | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLDN24 | c.386C>A p.S129* | Nonsense Mutation (SNP) | VAF 15/243 reads (6%) | called by muse, mutect2
- CNOT11 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX3X | c.1633A>T p.N545Y (on ENST00000399959; = p.N546Y on NM_001356.5) | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA10 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- FASN | c.456G>A p.G152= | Splice Region (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- GUCY1B1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- HHATL | c.795T>G p.F265L | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.342); called by muse, mutect2
- IL1R1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 180/413 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- JUNB | c.514_516dup p.V172dup | In Frame Ins (INS) | VAF 94/426 reads (22%) | called by mutect2, pindel, varscan2
- KNG1 | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LAS1L | c.2183A>G p.K728R | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LEPR | c.2713T>G p.S905A | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5R1 | c.81C>G p.C27W | Missense Mutation (SNP) | VAF 125/215 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- P3H3 | c.1213-8T>G | Splice Region (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.1787C>A p.P596H (on ENST00000295902; = p.P540H on NM_198859.4) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RNF217 | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- RXRG | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- SYNE1 | c.23625C>T p.A7875= (on ENST00000367255 / NM_182961.4; = p.A7804= on NM_033071.3) | Splice Region (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- TM2D3 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2
- TOMM7 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 76/370 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TRAF3 | c.732_753del p.N245Rfs*12 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- TRIM49B | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- UHMK1 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ANGPTL2 | c.594G>A p.A198= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs149444901; called by muse, mutect2
- B4GALNT1 | c.1431C>T p.S477= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as rs375772910; called by muse, mutect2, varscan2
- CLCN6 | c.2415A>T p.P805= | Silent (SNP) | VAF 114/284 reads (40%) | called by muse, mutect2, varscan2
- CRYBG3 | c.3771A>G p.Q1257= | Silent (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- GOLGA7 | c.63C>T p.G21= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1167764684; called by muse, mutect2
- KMT2C | c.4674G>T p.R1558= | Silent (SNP) | VAF 97/221 reads (44%) | called by muse, mutect2, varscan2
- LSM8 | c.18G>A p.E6= | Silent (SNP) | VAF 106/456 reads (23%) | catalogued as rs1386542380; called by muse, mutect2, varscan2
- MYH3 | c.4866C>T p.D1622= | Silent (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- OR5M11 | c.321A>G p.L107= | Silent (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- OR6A2 | c.822C>T p.D274= | Silent (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- PIEZO1 | c.1233G>A p.P411= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs764125181; called by muse, varscan2
- PRRT4 | c.87C>T p.I29= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs763558779; called by muse, mutect2, varscan2
- SLC6A3 | c.1830C>T p.R610= | Silent (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- TTN | c.21015G>A p.P7005= (on ENST00000591111; = p.P6078= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/272 reads (10%) | catalogued as rs773546767, COSV100597467; ClinVar: likely benign; called by muse, mutect2
- VPS4A | c.1041G>A p.R347= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- WDR90 | c.4224C>T p.G1408= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs749258865, COSV53472952; called by muse, mutect2, varscan2
- AC011410.1 | n.281G>A | RNA (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- AC024651.2 | n.1750G>A | RNA (SNP) | VAF 43/137 reads (31%) | catalogued as rs1361173015; called by muse, mutect2, varscan2
- AC103993.1 | n.943T>C | RNA (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-1339C>A | 5'UTR (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- ACD | c.716+20C>T | Intron (SNP) | VAF 14/148 reads (9%) | catalogued as rs749787512; called by muse, mutect2
- ADAMTS5 | c.*3639T>A | 3'UTR (SNP) | VAF 57/199 reads (29%) | called by muse, mutect2, varscan2
- AGAP3 | c.598+68G>T | Intron (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- AP3S2 | c.*2995C>T | 3'UTR (SNP) | VAF 15/20 reads (75%) | called by muse, mutect2, varscan2
- AQP6 | c.-152A>G | 5'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- ASCL4 | c.-522G>C | 5'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- BACH2 | c.*3467G>T | 3'UTR (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- BEST2 | c.*363C>T | 3'UTR (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- BMP6 | c.*1107_*1124del | 3'UTR (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- BRWD1 | c.6571+3143C>T | Intron (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- CCSAP | c.*2117T>C | 3'UTR (SNP) | VAF 110/181 reads (61%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65883498 A>G | 3'Flank (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- DMRT3 | c.455-149C>G | Intron (SNP) | VAF 68/208 reads (33%) | called by muse, mutect2
- ERN2 | c.*1G>T | 3'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- ETV1 | c.181+306G>A | Intron (SNP) | VAF 32/652 reads (5%) | called by muse, mutect2
- FAM186B | chr12:49584046 C>G | 3'Flank (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- FAM210A | c.*1500_*1503del | 3'UTR (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- FDX1 | c.-142G>T | 5'UTR (SNP) | VAF 27/33 reads (82%) | called by muse, mutect2, varscan2
- FEM1B | c.*3855A>T | 3'UTR (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- GAREM2 | c.*430C>T | 3'UTR (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- GCLC | c.*85A>T | 3'UTR (SNP) | VAF 26/37 reads (70%) | catalogued as COSV99988271; called by muse, mutect2, varscan2
- GKN2 | c.472+55C>T | Intron (SNP) | VAF 93/177 reads (53%) | called by muse, mutect2, varscan2
- GRM1 | c.*930T>G | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- H3-3B | chr17:75784631 C>T | 5'Flank (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- HHEX | c.362-80C>A | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- HS3ST1 | c.*5646A>T | 3'UTR (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- IP6K2 | c.202+381A>C | Intron (SNP) | VAF 86/320 reads (27%) | called by muse, mutect2, varscan2
- KANK4 | c.1900+746G>C | Intron (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- KIAA1109 | c.8591+111G>T | Intron (SNP) | VAF 59/90 reads (66%) | called by muse, mutect2, varscan2
- KIF26B | c.*276C>T | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- KLK3 | c.631-162C>G | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- KRTAP13-4 | c.*97C>T | 3'UTR (SNP) | VAF 124/466 reads (27%) | called by muse, mutect2, varscan2
- L3MBTL2 | c.1823-133A>G | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- LEP | c.*949T>A | 3'UTR (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- LIG3 | c.*2269A>G | 3'UTR (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.*63C>T | 3'UTR (SNP) | VAF 55/94 reads (59%) | catalogued as rs1038018707; called by muse, mutect2, varscan2
- LTB | c.162+136G>C | Intron (SNP) | VAF 41/64 reads (64%) | called by muse, mutect2, varscan2
- MAP1S | c.-5del | 5'UTR (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- MEIS1 | c.*79C>T | 3'UTR (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2, varscan2
- MFSD4A | c.*976T>C | 3'UTR (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- MST1L | n.1509G>C | RNA (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- MTHFD2 | c.286+46T>A | Intron (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- MTMR2 | c.*921T>G | 3'UTR (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- NEIL3 | c.*194C>T | 3'UTR (SNP) | VAF 43/70 reads (61%) | catalogued as rs531710574; called by muse, mutect2, varscan2
- NEK10 | c.*33C>T | 3'UTR (SNP) | VAF 111/395 reads (28%) | called by muse, mutect2, varscan2
- NOTCH1 | c.*1386G>A | 3'UTR (SNP) | VAF 42/59 reads (71%) | catalogued as rs1472797869; called by muse, mutect2, varscan2
- NRP2 | c.2440+9527T>A | Intron (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- NT5DC1 | c.*235T>G | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- OSBPL6 | c.*3711del | 3'UTR (DEL) | VAF 21/51 reads (41%) | catalogued as rs1172798629; called by mutect2, varscan2
- OTOP2 | c.510-172C>T | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- OXSR1 | chr3:38165466 A>G | 5'Flank (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- PELI2 | c.*2181del | 3'UTR (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- PLXNA3 | c.*270G>C | 3'UTR (SNP) | VAF 68/71 reads (96%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*1901T>G | 3'UTR (SNP) | VAF 28/130 reads (22%) | called by muse, varscan2
- PPP1R9A | c.-138G>A | 5'UTR (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- PXN | c.*1525C>T | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- RAD21 | c.-33+186T>C | Intron (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- RGS5 | c.*4779T>A | 3'UTR (SNP) | VAF 41/141 reads (29%) | called by muse, mutect2, varscan2
- RPRD1A | c.*50-1084T>C | Intron (SNP) | VAF 71/123 reads (58%) | catalogued as rs1002796353; called by muse, mutect2, varscan2
- RPS6KB2 | c.1155+36C>T | Intron (SNP) | VAF 75/223 reads (34%) | called by muse, mutect2, varscan2
- SCG5 | c.543+148C>T | Intron (SNP) | VAF 13/260 reads (5%) | called by muse, mutect2
- SESN3 | c.-72G>C | 5'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- SF3B1 | c.-28G>T | 5'UTR (SNP) | VAF 42/90 reads (47%) | catalogued as rs770895612; called by muse, mutect2, varscan2
- SLC9A4 | c.*219C>T | 3'UTR (SNP) | VAF 35/65 reads (54%) | catalogued as rs1370277586; called by muse, mutect2, varscan2
- SLC9A8 | c.*2346C>T | 3'UTR (SNP) | VAF 57/139 reads (41%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185340 A>G | 5'Flank (SNP) | VAF 53/196 reads (27%) | called by muse, mutect2, varscan2
- TBC1D12 | c.*2665T>A | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- TGFB2 | c.*2703C>A | 3'UTR (SNP) | VAF 61/108 reads (56%) | called by muse, mutect2, varscan2
- TM9SF2 | c.829-49T>A | Intron (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2
- TM9SF3 | c.*1293T>G | 3'UTR (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3810C>A | 3'UTR (SNP) | VAF 124/466 reads (27%) | called by mutect2, varscan2
- TMEM241 | c.*1712C>G | 3'UTR (SNP) | VAF 11/314 reads (4%) | called by muse, mutect2
- TXNDC5 | c.*1211T>G | 3'UTR (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- WDR72 | c.*2271T>C | 3'UTR (SNP) | VAF 45/81 reads (56%) | called by muse, mutect2, varscan2
- ZC3H7A | c.-34-131G>A | Intron (SNP) | VAF 75/168 reads (45%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.-894A>T | 5'UTR (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.*649G>A | 3'UTR (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- ZNF606 | chr19:58006467 G>A | 5'Flank (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
